Somatic mutation profile of tumor specimen TCGA-EJ-7321-01A (aliquot TCGA-EJ-7321-01A-31D-2260-08) from TCGA case TCGA-EJ-7321, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.8 years (21,108 days).
Specimen TCGA-EJ-7321-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed3d6fd4-bca7-4f49-98e8-bd991562ab0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-7321-10A (Blood Derived Normal), aliquot TCGA-EJ-7321-10A-01D-2260-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e2e5ea7-5c29-4555-9d51-fd8aac199704

The open-access MAF lists 29 somatic variants for this specimen: 20 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 8, Frame Shift Del 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALX3 | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 4/60 reads (7%) | catalogued as COSV63928570; called by muse, mutect2
- ATL2 | c.424G>A p.G142S | Missense Mutation (SNP) | VAF 33/379 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60050493; called by muse, mutect2
- CARMIL2 | c.2255G>A p.G752D | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.895); catalogued as COSV58023254; called by muse, mutect2
- CPAMD8 | c.2279C>A p.T760N (on ENST00000651564; = p.T713N on NM_015692.5) | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV52231183; called by muse, mutect2, varscan2
- FAM47A | c.226T>A p.F76I | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.277); catalogued as COSV60494002; called by muse, mutect2, varscan2
- FBXL2 | c.431C>A p.T144K | Missense Mutation (SNP) | VAF 21/335 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs1051425692, COSV52136880; called by muse, mutect2
- GPR108 | c.1351G>T p.V451F (on ENST00000264080 / NM_001080452.1; = p.V209F on NM_020171.2) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV51184201; called by muse, mutect2, varscan2
- HAO1 | c.802G>A p.V268M | Missense Mutation (SNP) | VAF 48/177 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as COSV66491076, COSV66491237; called by muse, mutect2, varscan2
- LTBP1 | c.2569G>A p.A857T (on ENST00000404816 / NM_206943.4; = p.A531T on NM_000627.4) | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.07); catalogued as COSV63180114; called by muse, mutect2, varscan2
- MUC17 | c.6626G>A p.S2209N | Missense Mutation (SNP) | VAF 74/596 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs772111228, COSV60280380; called by muse, mutect2, varscan2
- MYBPHL | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.201); catalogued as rs201690316, COSV64062167; called by muse, mutect2, varscan2
- OLFM4 | c.1404C>G p.D468E | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs747076426, COSV54575837, COSV99524520; called by muse, mutect2, varscan2
- OR2H2 | c.175T>G p.F59V | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as COSV63540891; called by muse, mutect2, varscan2
- OR56A1 | c.5C>G p.A2G | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as COSV57361805, COSV57362235; called by muse, mutect2, varscan2
- OR5D18 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 21/292 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV61736233; called by muse, mutect2
- SEMA3G | c.1699G>T p.G567C | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51593801; called by muse, mutect2, varscan2
- SMARCA5 | c.854C>T p.T285I | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV51642302; called by muse, mutect2, varscan2
- ZNF652 | c.779T>C p.L260P | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62946176; called by muse, mutect2, varscan2
- CUBN | c.7467del p.I2490Sfs*3 | Frame Shift Del (DEL) | VAF 35/262 reads (13%) | called by mutect2, pindel, varscan2
- KCTD19 | c.603_613del p.A202Vfs*23 | Frame Shift Del (DEL) | VAF 19/73 reads (26%) | called by mutect2, pindel, varscan2
- ADAMTS12 | c.1929G>A p.Q643= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV61255814; called by muse, mutect2, varscan2
- ADAMTS15 | c.2565C>T p.C855= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs780002833, COSV54503028; called by muse, mutect2, varscan2
- COL27A1 | c.2181A>G p.G727= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as rs755262175, COSV61921654; ClinVar: likely benign; called by muse, mutect2, varscan2
- DDX60 | c.534A>G p.Q178= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV67095135; called by muse, mutect2
- DHCR7 | c.336G>T p.T112= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV62794453; called by muse, mutect2, varscan2
- KIAA0930 | c.984C>T p.S328= (on ENST00000336156 / NM_001009880.2; = p.S333= on NM_015264.2) | Silent (SNP) | VAF 13/164 reads (8%) | catalogued as rs780041103, COSV52661982; called by muse, mutect2
- TGM4 | c.888C>T p.H296= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs1195447285, COSV56092762; called by muse, mutect2, varscan2
- ZP1 | c.1206C>T p.P402= | Silent (SNP) | VAF 37/247 reads (15%) | catalogued as rs151198562, COSV53923109; called by muse, mutect2, varscan2
- AL162726.3 | n.255+83148G>T | Intron (SNP) | VAF 19/490 reads (4%) | called by muse, mutect2
